MMRF case MMRF_1746 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c28922f7-a2da-4fbc-9c6d-e4d6f540734a

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.6 years (18,862 days); ISS stage: I; Days to last known disease status: 1,093 days (3.0 years); Days to last follow up: 1,093 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 153 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 153 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 160 days; Days to treatment end: 160 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 161 days; Days to treatment end: 161 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 274 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 1.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.084 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 17.3 mg/dL; Immunoglobulin G 24.4 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.69 g/L; Beta 2 Microglobulin 1.57 µg/mL; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Glucose 5.17 mmol/L; C-Reactive Protein 0.56 mg/dL.
- Day 138 (ECOG 0): M Protein 0.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 6.06 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.7 g/L; Beta 2 Microglobulin 1.44 µg/mL; Lactate Dehydrogenase 5.25 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 4.73 mmol/L.
- Day 222 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.562 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.522 mg/dL; Immunoglobulin G 8.83 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 4.57 mmol/L.
- Day 365 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.892 mg/dL; Immunoglobulin G 9.5 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.61 g/L; Beta 2 Microglobulin 1.36 µg/mL; Lactate Dehydrogenase 3.7 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.37 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.17 mmol/L.
- Day 456 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 9.58 g/L; Immunoglobulin A 1.39 g/L; Immunoglobulin M 0.45 g/L; Beta 2 Microglobulin 1.49 µg/mL; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.
- Day 547 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 1.99 g/L; Immunoglobulin A 11.9 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 5.56 mmol/L.
- Day 638 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.905 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 2.17 g/L; Immunoglobulin M 0.56 g/L; Beta 2 Microglobulin 1.31 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 4.73 mmol/L.
- Day 729 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 2.44 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 1.31 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 5.12 mmol/L.
- Day 817: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 2.2 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 1.27 µg/mL; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.06 mmol/L.
- Day 908 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 2.28 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 6.93 mmol/L.
- Day 999 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 12.8 g/L; Immunoglobulin A 2.6 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.06 mmol/L.
- Day 1,093 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.996 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.976 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 2.41 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.11 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day 1: Weight: 79 kg; Height: 162 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1746_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1746_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
